Gene-level copy-number profile of tumor specimen C3L-06922-01 from CPTAC case C3L-06922, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 53.2 years (19,439 days).
Specimen C3L-06922-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e468c00c-1915-4bcf-a7a9-e388c52bacd8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06922-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/8dd7ecc7-4b52-4375-8c9a-3b89b426db23

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 4,549; copy number 2: 39,749; copy number 3: 14,565; copy number 4: 35.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,747,277–61,251,459, 8 genes: FHIT, AC093418.1, AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr7:111,091,006–111,125,454, 1 gene (within-gene range 0–3): LRRN3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,693. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
